Gene-level copy-number profile of tumor specimen AP-XVLY-FE from APOLLO case AP-XVLY, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3.
Specimen AP-XVLY-FE: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc650e51-d7e4-43a0-bcbf-0491a2157eee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-XVLY-E5 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/6be1cc8c-ff1c-4b80-b3bf-b15cece1c129

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 554; copy number 2: 2,547; copy number 3: 31,098; copy number 4: 21,361; copy number 5: 2,863; copy number 6: 2; copy number 7: 23; copy number 8: 53; copy number 9: 90; copy number 10: 146; copy number 11: 89; copy number 12: 8; copy number 13: 20; copy number 17: 1; copy number 20: 23; copy number 22: 21; copy number 23: 8; copy number 27: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 486 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:28,765,640–50,416,461, 313 genes, copy number 8–12 (broad region; genes not listed).
- chr21:9,026,821–9,059,060, 2 genes, copy number 7: CDRT15P9, CR392039.4.
- chr22:18,076,527–18,177,397, 8 genes, copy number 9: AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18.
- chr22:18,615,581–18,861,049, 11 genes, copy number 11–17: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7.
- chr22:19,046,162–21,451,463, 134 genes, copy number 7–27 (broad region; genes not listed).
- chr22:23,179,704–23,318,037, 1 gene, copy number 8 (within-gene range 5–8): BCR.
- chr22:23,261,782–23,608,407, 17 genes, copy number 8: RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4.

Autosomal genes at a single copy (total copy number 1): 42. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
